Somatic mutation profile of tumor specimen MP2PRT-PASPAA-TMP1-A (aliquot MP2PRT-PASPAA-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASPAA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,055 days).
Specimen MP2PRT-PASPAA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f75022d-e327-48c9-8a38-b9b5da6ee34b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPAA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPAA-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4a78c60-ec8d-4f3f-a45d-94c6f453bdf9

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 87/262 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNNM1 | c.2379C>G p.C793W | Missense Mutation (SNP) | VAF 117/458 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs369373358, COSV63201261; called by muse, mutect2, varscan2
- DMD | c.8426G>A p.R2809H | Missense Mutation (SNP) | VAF 149/342 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs778331600, COSV100627981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLPP4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 37/593 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367975027; called by muse, mutect2
- C5orf15 | c.46_47insGGGGACA p.K16Rfs*39 | Frame Shift Ins (INS) | VAF 67/502 reads (13%) | called by mutect2, pindel, varscan2
- GRK2 | c.224_226dup p.H75dup | In Frame Ins (INS) | VAF 53/340 reads (16%) | called by pindel, varscan2*
- LIMD1 | c.688_689insAACCC p.R230Qfs*7 | Frame Shift Ins (INS) | VAF 113/384 reads (29%) | called by pindel, varscan2
- MAGEB18 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VDAC1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 51/387 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM181B | c.333G>A p.A111= | Silent (SNP) | VAF 53/483 reads (11%) | catalogued as rs373232991; called by muse, mutect2, varscan2
- NUPR2 | c.94C>T p.L32= | Silent (SNP) | VAF 113/397 reads (28%) | catalogued as rs750930934; called by muse, mutect2, varscan2
- SLAMF7 | c.360C>T p.Y120= | Silent (SNP) | VAF 66/241 reads (27%) | catalogued as rs368468809; called by muse, mutect2, varscan2
